Somatic mutation profile of tumor specimen ALCH-AEOF-TTP1-A (aliquot ALCH-AEOF-TTP1-A-2-0-D-A673-36) from ALCHEMIST case ALCH-AEOF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.4 years (19,886 days).
Specimen ALCH-AEOF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a38e994-479c-42f9-9e72-5304c034893c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEOF-NB1-A (Blood Derived Normal), aliquot ALCH-AEOF-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06bce9b0-c04c-4371-8791-8d9dc0ab5614

The open-access MAF lists 565 somatic variants for this specimen: 424 protein-altering or splice-affecting, 92 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 364, Silent 92, Nonsense Mutation 34, Intron 25, Splice Site 14, 5'UTR 8, Frame Shift Del 6, RNA 6, 3'UTR 4, 3'Flank 4, Splice Region 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL17A1 | c.3156C>T p.G1052= | Silent (SNP) | VAF 31/238 reads (13%) | catalogued as rs760714959, CS152543; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 67/354 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 35/127 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALG13 | c.2090G>A p.R697H | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1416055334, COSV52635322; called by muse, mutect2
- AMER2 | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV63438863; called by muse, mutect2, varscan2
- AMPH | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs769186615; called by muse, mutect2, varscan2
- AP001781.2 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 6/115 reads (5%) | catalogued as COSV99499532; called by muse, mutect2
- APCS | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV99661220; called by muse, mutect2, varscan2
- ARHGAP31 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 47/316 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1247569081; called by muse, mutect2, varscan2
- ARHGAP33 | c.3236C>G p.P1079R | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as COSV99137389; called by muse, mutect2, varscan2
- ASXL3 | c.661C>G p.P221A | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52457906; called by muse, mutect2, varscan2
- ATP11C | c.2870G>T p.G957V | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.322); catalogued as COSV59566532; called by muse, mutect2
- ATP6V0A2 | c.2560A>T p.S854C | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.122); catalogued as rs773898986; called by muse, mutect2, varscan2
- BCHE | c.656G>A p.S219N | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs1367718556; called by muse, mutect2, varscan2
- CADM3 | c.150C>A p.C50* (on ENST00000368125 / NM_001127173.3; = p.C84* on NM_021189.5) | Nonsense Mutation (SNP) | VAF 46/214 reads (21%) | catalogued as COSV63683592; called by muse, mutect2, varscan2
- CASS4 | c.1348A>T p.K450* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100824749; called by muse, mutect2, varscan2
- CCDC137 | c.775G>T p.V259L | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV61303773; called by muse, mutect2
- CCDC168 | c.5408G>A p.R1803H | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs749469549, COSV70556023; called by muse, mutect2, varscan2
- CCSER2 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs201743744; called by muse, mutect2, varscan2
- CD44 | c.136C>G p.R46G | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs121909545, COSV53536915; called by muse, mutect2, varscan2
- CDH24 | c.2068G>A p.G690S | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57458675; called by muse, mutect2, varscan2
- CDH7 | c.1718G>A p.S573N | Missense Mutation (SNP) | VAF 25/290 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1199155188; called by muse, mutect2
- CHSY1 | c.576G>T p.E192D | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs148344653; called by muse, mutect2, varscan2
- CLSPN | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 35/334 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV52057311; called by muse, mutect2, varscan2
- CNGB3 | c.2288T>A p.V763E | Missense Mutation (SNP) | VAF 33/308 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100183335; called by muse, mutect2, varscan2
- COL11A1 | c.274+1G>T p.X92_splice | Splice Site (SNP) | VAF 51/237 reads (22%) | catalogued as COSV62174701; called by muse, mutect2, varscan2
- COL11A1 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 26/193 reads (13%) | catalogued as COSV100615367, COSV62195294; called by muse, mutect2, varscan2
- COL4A5 | c.4325G>T p.G1442V | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM094057, CM990411; called by muse, mutect2
- COL5A3 | c.5096G>A p.R1699Q | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs370271810; called by muse, mutect2, varscan2
- CPED1 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 36/149 reads (24%) | catalogued as rs200483154; called by muse, mutect2, varscan2
- CSH1 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.907); catalogued as rs766343963, COSV100298405, COSV60242550; called by muse, mutect2
- CSMD3 | c.4736C>A p.P1579H (on ENST00000297405 / NM_001363185.1; = p.P1475H on NM_052900.3) | Missense Mutation (SNP) | VAF 234/428 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52198184, COSV52274800; called by muse, mutect2, varscan2
- CSMD3 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 287/589 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52149077; called by muse, mutect2, varscan2
- CUBN | c.4351-1G>T p.X1451_splice | Splice Site (SNP) | VAF 65/337 reads (19%) | catalogued as COSV100912592; called by muse, mutect2, varscan2
- DACT1 | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV60021569; called by muse, mutect2, varscan2
- DCAF12L1 | c.740C>A p.P247Q | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV64421193; called by muse, mutect2, varscan2
- DCAF4L2 | c.1111C>A p.R371S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.241); catalogued as COSV100150800; called by muse, mutect2
- DCC | c.3922C>A p.Q1308K | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.593); catalogued as COSV101473539; called by muse, mutect2, varscan2
- DCSTAMP | c.1030-1G>C p.X344_splice | Splice Site (SNP) | VAF 16/102 reads (16%) | catalogued as COSV99887112; called by muse, mutect2, varscan2
- DEFB113 | c.89A>G p.E30G | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs1475199076; called by muse, mutect2, varscan2
- DIAPH3 | c.1352A>G p.Y451C (on ENST00000400324 / NM_001042517.2; = p.Y188C on NM_030932.3) | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1204841723; called by muse, mutect2, varscan2
- DSE | c.1978G>T p.A660S | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV99045278; called by muse, mutect2, varscan2
- DYNC2I1 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.831); catalogued as COSV68104153; called by muse, mutect2, varscan2
- ELAVL4 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1427053388, COSV63916082; called by muse, mutect2, varscan2
- ELMO1 | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.931); catalogued as rs776394175, COSV60297388, COSV60304608; called by muse, mutect2, varscan2
- ENPP7 | c.68C>A p.P23Q | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60385748; called by muse, mutect2, varscan2
- ESRRG | c.1237C>G p.R413G | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63161834; called by muse, mutect2
- FANCM | c.3622G>T p.G1208C | Missense Mutation (SNP) | VAF 60/269 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV57497409; called by muse, mutect2, varscan2
- FAT3 | c.11811C>G p.Y3937* | Nonsense Mutation (SNP) | VAF 21/121 reads (17%) | catalogued as COSV53138041; called by muse, mutect2, varscan2
- FBXL13 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1362026713, COSV57538408; called by muse, mutect2
- FGF5 | c.574C>A p.L192M | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56891732; called by muse, mutect2, varscan2
- GABRG1 | c.987T>A p.Y329* | Nonsense Mutation (SNP) | VAF 27/293 reads (9%) | catalogued as COSV99777484; called by muse, mutect2
- GBE1 | c.1802A>G p.Q601R | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.147); catalogued as rs1215596601; called by muse, mutect2, varscan2
- GHDC | c.123G>T p.W41C | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56987490; called by muse, mutect2, varscan2
- GHSR | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53837321; called by muse, mutect2, varscan2
- HIVEP1 | c.8084G>A p.R2695Q | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1475339408, COSV101045708; called by muse, mutect2, varscan2
- HLA-C | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66115079; called by muse, varscan2
- IGKV1-16 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs781184992; called by muse, mutect2
- INO80 | c.2958G>T p.Q986H | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs758299239; called by muse, mutect2, varscan2
- IQCF5 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs913806331, COSV71306898; called by muse, mutect2, varscan2
- ITGBL1 | c.656A>G p.Q219R | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs920780629; called by muse, varscan2
- KCNB2 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV73051019; called by muse, mutect2
- KCNT2 | c.3278T>C p.I1093T | Missense Mutation (SNP) | VAF 75/308 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV99655358; called by muse, mutect2, varscan2
- KIAA0753 | c.722G>T p.R241I | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV63818941; called by muse, mutect2, varscan2
- KLHL13 | c.944C>A p.A315D | Missense Mutation (SNP) | VAF 98/343 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53247888; called by muse, mutect2, varscan2
- LRP1B | c.822G>A p.W274* | Nonsense Mutation (SNP) | VAF 77/312 reads (25%) | catalogued as COSV101262157; called by muse, mutect2, varscan2
- LRRTM4 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs1181915406, COSV69139030, COSV69142914; called by muse, mutect2, varscan2
- LYPD2 | c.191A>G p.Q64R | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1328892129; called by muse, mutect2
- MC3R | c.537C>A p.F179L | Missense Mutation (SNP) | VAF 90/340 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1568966470; called by muse, mutect2, varscan2
- MED17 | c.1526del p.G509Efs*3 | Frame Shift Del (DEL) | VAF 44/288 reads (15%) | catalogued as rs1234776484; called by mutect2, pindel, varscan2
- MIA3 | c.3682A>G p.T1228A | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1450776972; called by muse, mutect2, varscan2
- MRC2 | c.4147G>T p.A1383S | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV57641673, COSV57645123; called by muse, mutect2, varscan2
- MYF5 | c.278G>C p.R93P | Missense Mutation (SNP) | VAF 81/279 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57356615; called by muse, mutect2, varscan2
- MYH7 | c.3236G>A p.R1079Q | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as rs727504342, CM102044, COSV100806092; ClinVar: uncertain significance; called by mutect2, varscan2
- MYH7B | c.2458G>A p.V820I | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs376856126; called by muse, mutect2, varscan2
- MYLK | c.3329C>T p.A1110V | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.154); catalogued as rs1262789998; called by muse, mutect2, varscan2
- MYLK4 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1391037353; called by muse, mutect2, varscan2
- MYO18B | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as rs780457718; called by muse, mutect2, varscan2
- NLRP3 | c.2827G>T p.V943L | Missense Mutation (SNP) | VAF 81/296 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs199878892; called by muse, mutect2, varscan2
- NOTCH4 | c.4198C>G p.R1400G | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.29); catalogued as COSV66678499; called by muse, mutect2, varscan2
- NPAP1 | c.1798C>A p.L600I | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.266); catalogued as COSV61505094, COSV61509813; called by muse, mutect2, varscan2
- NRXN2 | c.4523C>A p.T1508K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV99632381; called by muse, varscan2
- NUP210 | c.5393G>C p.S1798T | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54403170; called by muse, mutect2, varscan2
- OLFML2B | c.2125G>A p.V709I | Missense Mutation (SNP) | VAF 18/297 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54194658; called by muse, mutect2
- OR11A1 | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs373751127; called by muse, mutect2
- OR5AC2 | c.341G>T p.C114F | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV100684323; called by muse, mutect2, varscan2
- OR8I2 | c.778C>G p.Q260E | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV100136218; called by muse, mutect2
- OR8J1 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57317134; called by mutect2, varscan2
- PCDH15 | c.5051C>A p.A1684E (on ENST00000644397 / NM_001354429.2; = p.A1626E on NM_001142771.2) | Missense Mutation (SNP) | VAF 161/600 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.215); catalogued as rs752801351, COSV100905466; called by muse, mutect2, varscan2
- PCDHA3 | c.2321C>A p.P774H | Missense Mutation (SNP) | VAF 94/321 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63541409; called by muse, mutect2, varscan2
- PDE2A | c.1700C>G p.A567G | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV57803429; called by muse, mutect2, varscan2
- PDE6H | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 82/244 reads (34%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.085); catalogued as COSV99844102; called by muse, varscan2
- PLD4 | c.397G>C p.V133L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV66915520; called by mutect2, varscan2
- PLEKHG5 | c.1015G>T p.E339* (on ENST00000400915 / NM_001042663.3; = p.E302* on NM_020631.6) | Nonsense Mutation (SNP) | VAF 62/258 reads (24%) | catalogued as COSV100556170, COSV61702357; called by muse, mutect2, varscan2
- PLG | c.528C>A p.C176* | Nonsense Mutation (SNP) | VAF 71/266 reads (27%) | catalogued as rs558599800, COSV51984719; called by muse, mutect2, varscan2
- PLP1 | c.543G>C p.W181C | Missense Mutation (SNP) | VAF 107/390 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM002828, COSV58276060; called by muse, mutect2, varscan2
- POTEC | c.196C>A p.H66N | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.049); catalogued as COSV100743277; called by muse, mutect2
- POTEM | c.950C>A p.S317* | Nonsense Mutation (SNP) | VAF 27/125 reads (22%) | catalogued as COSV101193836; called by mutect2, varscan2
- PRND | c.9G>T p.K3N | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as rs768711861; called by muse, mutect2, varscan2
- PROS1 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs121918476, CM057362, CM991071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RADIL | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV101271190; called by muse, mutect2
- RANBP2 | c.5298G>T p.E1766D | Missense Mutation (SNP) | VAF 67/271 reads (25%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs140653325; called by muse, mutect2, varscan2
- RBM19 | c.1811A>C p.Q604P | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as rs990557322; called by muse, mutect2, varscan2
- RGR | c.684G>T p.W228C | Missense Mutation (SNP) | VAF 105/393 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212697754, COSV100812953; called by muse, mutect2, varscan2
- RGS1 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66504620; called by muse, varscan2
- RTN1 | c.308C>A p.S103* | Nonsense Mutation (SNP) | VAF 17/87 reads (20%) | catalogued as COSV50718708; called by muse, mutect2
- RYR1 | c.13187C>T p.P4396L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1444540296; called by muse, mutect2, varscan2
- SCAPER | c.2030A>G p.K677R | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.178); catalogued as rs1160566430; called by muse, mutect2, varscan2
- SEC31A | c.3086G>T p.G1029V (on ENST00000355196 / NM_001318120.1; = p.G990V on NM_016211.4) | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.548); catalogued as COSV52341470; called by muse, mutect2
- SHOX | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309060961; called by muse, mutect2
- SKIDA1 | c.2597C>A p.P866Q | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71610808; called by mutect2, varscan2
- SMARCAD1 | c.1651G>A p.V551I | Missense Mutation (SNP) | VAF 48/427 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.693); catalogued as rs925841496; called by muse, mutect2, varscan2
- SNX9 | c.43C>G p.P15A | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs1475867742; called by muse, mutect2, varscan2
- SOGA1 | c.1454G>T p.G485V | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs751198117, COSV99413027; called by muse, mutect2, varscan2
- SORBS2 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.253); catalogued as rs1214627955; called by muse, mutect2
- SPTA1 | c.3220C>T p.R1074C | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs569406964, COSV63749209; called by muse, mutect2
- STAC | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 22/253 reads (9%) | catalogued as COSV56206657; called by muse, mutect2
- STAM | c.1327G>C p.V443L | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782429739; called by muse, mutect2, varscan2
- STOML3 | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs147878470, COSV65512160; called by muse, mutect2
- TANC2 | c.3226C>T p.R1076C | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368122235, COSV67329949; called by muse, mutect2, varscan2
- TCHH | c.4625G>A p.R1542H | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.662); catalogued as rs548533493; called by muse, mutect2, varscan2
- TEX11 | c.2366C>G p.P789R (on ENST00000344304; = p.P774R on NM_031276.3) | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100721426; called by muse, mutect2, varscan2
- TEX13C | c.2847G>T p.K949N | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1355402058; called by muse, mutect2
- TGIF2LX | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs753807305, COSV99383532; called by muse, mutect2, varscan2
- TLL1 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 56/344 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50305017; called by muse, mutect2, varscan2
- TLL1 | c.967C>G p.R323G | Missense Mutation (SNP) | VAF 91/369 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV50342931; called by muse, mutect2, varscan2
- TMEM63C | c.222C>A p.H74Q | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.166); catalogued as rs751143240; called by muse, mutect2, varscan2
- TNR | c.2704C>A p.Q902K | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV54898609; called by muse, varscan2
- TOLLIP | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55135782; called by muse, mutect2, varscan2
- TRIM21 | c.1328G>T p.R443L | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.88); catalogued as COSV54345244; called by muse, mutect2, varscan2
- TRIM50 | c.858C>A p.F286L | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.173); catalogued as COSV60793682, COSV60795944; called by muse, mutect2, varscan2
- TRIM58 | c.517-1G>C p.X173_splice | Splice Site (SNP) | VAF 28/106 reads (26%) | catalogued as COSV63569630; called by muse, mutect2
- TSKU | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.434); catalogued as rs1463228408; called by muse, mutect2
- URI1 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 56/285 reads (20%) | catalogued as COSV100369017; called by muse, varscan2
- VRTN | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV56440426; called by muse, mutect2, varscan2
- ZNF227 | c.2212C>T p.H738Y | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57311803; called by muse, mutect2, varscan2
- ZNF267 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100339553; called by muse, mutect2, varscan2
- ZNF446 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as rs773922865; called by muse, mutect2, varscan2
- ZNF479 | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58638045; called by muse, mutect2
- ZNF521 | c.2563G>T p.E855* | Nonsense Mutation (SNP) | VAF 14/220 reads (6%) | catalogued as COSV64126122; called by muse, mutect2
- ZNF560 | c.910C>A p.Q304K | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV56867231; called by muse, mutect2, varscan2
- ZNF716 | c.163del p.L55Wfs*10 | Frame Shift Del (DEL) | VAF 22/211 reads (10%) | catalogued as COSV70783259; called by mutect2, varscan2
- ZNF786 | c.1138A>T p.M380L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV60275801; called by muse, mutect2, varscan2
- ZP4 | c.316C>A p.P106T | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1463718443; called by muse, mutect2
- ZSCAN10 | c.1934G>T p.R645L (on ENST00000252463; = p.R700L on NM_032805.3) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV52970923; called by muse, mutect2, varscan2
- ABCA2 | c.2165A>T p.Y722F (on ENST00000614293; = p.Y692F on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- ABCA8 | c.4156-1G>T p.X1386_splice | Splice Site (SNP) | VAF 50/135 reads (37%) | called by muse, mutect2, varscan2
- ABCA9 | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 90/227 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCB5 | c.3424C>G p.P1142A (on ENST00000404938 / NM_001163941.2; = p.P697A on NM_178559.6) | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ABLIM1 | c.449A>T p.Y150F | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ACAP2 | c.2118A>T p.E706D | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACLY | c.236A>T p.D79V | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ACTA1 | c.457A>T p.I153F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ADAMTSL1 | c.5064G>T p.Q1688H | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADCY7 | c.1748G>T p.R583L | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ADGRG1 | c.266A>T p.H89L | Missense Mutation (SNP) | VAF 83/414 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ADGRG4 | c.6835T>A p.F2279I | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADGRL4 | c.1921G>T p.A641S | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- AFF3 | c.3353C>T p.S1118F | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- AHNAK2 | c.10921C>A p.P3641T | Missense Mutation (SNP) | VAF 57/321 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- AK8 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- AKAP11 | c.2353G>T p.A785S | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AKNAD1 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ALG13 | c.2821C>A p.P941T | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ALKBH1 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, varscan2
- ALMS1 | c.2428G>C p.A810P | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANK2 | c.4248+2T>A p.X1416_splice | Splice Site (SNP) | VAF 60/229 reads (26%) | called by muse, mutect2, varscan2
- ANKRD17 | c.6460C>T p.P2154S | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.16); called by muse, mutect2
- ANKRD36 | c.2479G>T p.A827S | Missense Mutation (SNP) | VAF 72/460 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.98); called by muse, varscan2
- ANO7 | c.254C>G p.T85R (on ENST00000274979; = p.T31R on NM_001001666.4) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.266); called by mutect2, varscan2
- ANTKMT | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- APOBEC3A | c.388T>A p.Y130N | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF18 | c.2423G>T p.R808L (on ENST00000359920 / NM_001130955.2; = p.R704L on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ARHGEF2 | c.2872C>G p.P958A (on ENST00000361247 / NM_001162383.2; = p.P930A on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- ASB18 | c.595G>T p.G199W | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASIC5 | c.168C>G p.N56K | Missense Mutation (SNP) | VAF 35/317 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ASTN2 | c.1272C>A p.S424R (on ENST00000313400 / NM_001365069.1; = p.S373R on NM_014010.5) | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated, low confidence (0.63); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ASXL3 | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.274); called by muse, mutect2
- ATF7IP | c.3178C>T p.H1060Y | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- ATP10D | c.982C>G p.L328V | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- BEND3 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 35/112 reads (31%) | called by muse, mutect2, varscan2
- BPIFB6 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 32/139 reads (23%) | called by muse, mutect2, varscan2
- BRWD3 | c.3337G>T p.D1113Y | Missense Mutation (SNP) | VAF 40/316 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, varscan2
- BTK | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 26/399 reads (7%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.572); called by muse, mutect2
- C5orf51 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.121); called by muse, mutect2
- C8A | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 69/428 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CACNA1D | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 67/286 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CAMK4 | c.1294C>A p.L432I | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC110 | c.1807G>T p.G603* | Nonsense Mutation (SNP) | VAF 60/240 reads (25%) | called by muse, varscan2
- CCDC110 | c.1744C>A p.Q582K | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.337); called by muse, varscan2
- CCDC168 | c.18138T>A p.N6046K | Missense Mutation (SNP) | VAF 34/309 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- CCDC168 | c.6169G>A p.G2057R | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC191 | c.1392_1409del p.P465_G470del | In Frame Del (DEL) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- CCSER1 | c.2626T>A p.Y876N | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD164L2 | c.220A>T p.S74C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, varscan2
- CD99L2 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.285); called by muse, mutect2
- CDH23 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- CDK14 | c.1078G>C p.V360L (on ENST00000380050 / NM_001287135.2; = p.V342L on NM_012395.3) | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- CEP170 | c.2141G>T p.G714V | Missense Mutation (SNP) | VAF 66/570 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- CFAP46 | c.8110C>T p.Q2704* | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- CHORDC1 | c.654G>T p.W218C | Missense Mutation (SNP) | VAF 65/261 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHRM3 | c.1153T>A p.S385T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CHST8 | c.1053G>T p.M351I | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- CLDN34 | c.350G>C p.R117T | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- COL11A1 | c.2953G>T p.G985W | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A5 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- COL4A6 | c.3085C>G p.P1029A | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPB2 | c.789C>A p.H263Q | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- CPT1C | c.1659G>T p.K553N | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUL9 | c.2824C>T p.Q942* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- CYP11B1 | c.393G>T p.L131F | Missense Mutation (SNP) | VAF 26/422 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2
- DCC | c.1600C>A p.L534M | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- DHX30 | c.2189C>T p.A730V (on ENST00000445061 / NM_138615.3; = p.A691V on NM_014966.3) | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DPPA4 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 49/218 reads (22%) | called by muse, mutect2, varscan2
- DSC2 | c.1022G>T p.C341F | Missense Mutation (SNP) | VAF 52/295 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, varscan2
- EIF3B | c.2105T>C p.L702P | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- EPHA3 | c.1540G>T p.A514S | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM160A1 | c.2445A>G p.I815M | Missense Mutation (SNP) | VAF 69/289 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FANCM | c.2005A>T p.M669L | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT4 | c.3883del p.L1295Sfs*7 | Frame Shift Del (DEL) | VAF 51/208 reads (25%) | called by mutect2, pindel, varscan2
- FBXO10 | c.559G>C p.A187P | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FCER1A | c.284A>C p.H95P | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.155); called by muse, mutect2
- FCGBP | c.951G>T p.L317F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- FDCSP | c.31A>T p.I11F | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- FER1L5 | c.6180T>A p.D2060E (on ENST00000623019; = p.D2024E on NM_001293083.2) | Missense Mutation (SNP) | VAF 89/280 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FER1L6 | c.911G>C p.W304S | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FIG4 | c.186A>T p.E62D | Missense Mutation (SNP) | VAF 86/301 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- FLNC | c.379C>A p.L127M | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRG2C | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FRY | c.7663C>T p.L2555F | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, varscan2
- FTO | c.810G>T p.W270C | Missense Mutation (SNP) | VAF 38/300 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FZD6 | c.1202A>T p.Q401L | Missense Mutation (SNP) | VAF 171/588 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GAD2 | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 16/167 reads (10%) | called by muse, mutect2, varscan2
- GAPDHS | c.687G>C p.L229F | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GHRHR | c.409C>A p.H137N | Missense Mutation (SNP) | VAF 94/524 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- GLI3 | c.523A>T p.R175W | Missense Mutation (SNP) | VAF 78/350 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GLI4 | c.843C>A p.N281K | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- GPI | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- GPR161 | c.883C>A p.L295I | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- GPR33 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- GPRASP1 | c.754G>C p.G252R | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- GRM5 | c.2054C>A p.P685H | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM8 | c.1977G>T p.M659I | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- H1-4 | c.565G>C p.A189P | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- HECTD4 | c.9197C>T p.S3066F | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMGCLL1 | c.801G>C p.M267I | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HSD17B3 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HYDIN | c.13534C>A p.L4512M | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ICE1 | c.4724G>T p.R1575I | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- IFIH1 | c.1943G>T p.G648V | Missense Mutation (SNP) | VAF 75/332 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- IFT172 | c.815G>T p.R272I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- IFTAP | c.467G>T p.S156I | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IMPG2 | c.3489dup p.E1164* | Frame Shift Ins (INS) | VAF 39/234 reads (17%) | called by mutect2, pindel, varscan2
- INO80 | c.2959G>T p.V987F | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQSEC2 | c.944G>C p.R315P (on ENST00000642864 / NM_001111125.3; = p.R110P on NM_015075.2) | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGA6 | c.156G>T p.W52C | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ITGAM | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNA4 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCND3 | c.1450del p.E484Kfs*112 | Frame Shift Del (DEL) | VAF 38/354 reads (11%) | called by mutect2, pindel, varscan2
- KCNK16 | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- KCNK6 | c.800A>T p.E267V | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- KCNT2 | c.2631G>T p.M877I | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KCTD3 | c.2099C>A p.A700E | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.051); called by muse, mutect2
- KEL | c.1819G>T p.A607S | Missense Mutation (SNP) | VAF 61/333 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.241); called by mutect2, varscan2
- KIAA1217 | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP10-6 | c.899C>A p.S300Y | Missense Mutation (SNP) | VAF 32/268 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRTAP24-1 | c.646A>G p.T216A | Missense Mutation (SNP) | VAF 73/409 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KXD1 | c.488A>T p.N163I | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- LCOR | c.4320G>T p.R1440S | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- LGR6 | c.109del p.A37Pfs*31 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- LILRA1 | c.1423C>A p.L475I | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- LIPF | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LMNTD1 | c.78G>T p.M26I | Missense Mutation (SNP) | VAF 78/347 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC10B | c.227T>C p.F76S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC4C | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- LTB | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- LYPD2 | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.228); called by muse, mutect2
- MAGEB6B | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MAP3K7 | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MASP1 | c.1470C>A p.H490Q | Missense Mutation (SNP) | VAF 65/316 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MBNL1 | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MDGA2 | c.1862G>T p.G621V (on ENST00000399232 / NM_001113498.2; = p.G323V on NM_182830.4) | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); called by muse, mutect2
- MMEL1 | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMUT | c.2030G>C p.G677A | Missense Mutation (SNP) | VAF 40/275 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.965); called by muse, varscan2
- MPC2 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- MPDZ | c.2851G>T p.V951L | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH2B | c.4451G>C p.R1484T | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- MS4A1 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.739); called by muse, mutect2
- MTMR4 | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.33238G>T p.E11080* | Nonsense Mutation (SNP) | VAF 23/155 reads (15%) | called by muse, mutect2, varscan2
- MUC16 | c.22750A>T p.R7584* | Nonsense Mutation (SNP) | VAF 20/183 reads (11%) | called by muse, mutect2
- MUC16 | c.17038C>A p.P5680T | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MXRA5 | c.4291C>A p.P1431T | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.026); called by muse, mutect2
- MYB | c.703A>C p.T235P | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYCN | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYO5A | c.4495G>C p.G1499R | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); called by muse, mutect2
- MYRFL | c.2147G>C p.R716P | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NBPF6 | c.1861G>T p.A621S | Missense Mutation (SNP) | VAF 28/309 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- NLRC3 | c.2431C>A p.L811M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NME7 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- NME7 | c.755-1G>T p.X252_splice | Splice Site (SNP) | VAF 20/160 reads (13%) | called by muse, mutect2, varscan2
- NR5A2 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.112); called by mutect2, varscan2
- NRXN2 | c.2339C>A p.T780N | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NWD1 | c.2338G>T p.D780Y | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- OR10J3 | c.141G>T p.M47I | Missense Mutation (SNP) | VAF 24/327 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- OR11H2 | c.796C>A p.P266T (on ENST00000556246; = p.P277T on NM_001197287.1) | Missense Mutation (SNP) | VAF 68/566 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- OR2AP1 | c.602C>A p.A201E | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2J1 | c.551C>G p.A184G | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR51S1 | c.608C>G p.A203G | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- OR52N1 | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- OTOG | c.7024C>A p.Q2342K | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); called by muse, mutect2
- OTOL1 | c.490G>T p.G164* | Nonsense Mutation (SNP) | VAF 32/187 reads (17%) | called by muse, mutect2, varscan2
- OTUD5 | c.881G>T p.R294L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OVCH2 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P3H3 | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PAK5 | c.757A>T p.S253C | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- PCDH11X | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 61/412 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PCDH11X | c.2900C>G p.P967R | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDH15 | c.5467C>A p.P1823T | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PCNT | c.5995-1G>T p.X1999_splice | Splice Site (SNP) | VAF 65/312 reads (21%) | called by muse, mutect2, varscan2
- PDGFA | c.388A>C p.T130P | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- PHF3 | c.2635G>T p.E879* | Nonsense Mutation (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- PIEZO2 | c.2289G>A p.W763* | Nonsense Mutation (SNP) | VAF 13/250 reads (5%) | called by muse, mutect2
- PIWIL3 | c.1183A>C p.I395L | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PLCB4 | c.1622C>A p.T541N | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLD3 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHM2 | c.922A>G p.T308A | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.05); called by muse, mutect2
- POTEF | c.1552A>G p.K518E | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by mutect2, varscan2
- POTEH | c.120G>T p.K40N | Missense Mutation (SNP) | VAF 72/712 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- PPP4R2 | c.739dup p.R247Kfs*5 | Frame Shift Ins (INS) | VAF 63/292 reads (22%) | called by mutect2, pindel, varscan2
- PRAME | c.849G>T p.Q283H | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2
- PRAMEF7 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 50/571 reads (9%) | called by muse, mutect2
- PRDM10 | c.850A>G p.M284V | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- PRG3 | c.506G>T p.W169L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PRKCB | c.529+1G>T p.X177_splice | Splice Site (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- PRMT2 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 23/136 reads (17%) | called by muse, mutect2, varscan2
- PRSS41 | c.940C>A p.H314N | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PSMB9 | c.357G>T p.M119I | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTCH1 | c.1858A>G p.S620G | Missense Mutation (SNP) | VAF 57/338 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PTGDS | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PTPN18 | c.757-1G>T p.X253_splice | Splice Site (SNP) | VAF 55/185 reads (30%) | called by muse, mutect2, varscan2
- PTPRT | c.4270C>A p.L1424M | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- PYGL | c.2370G>T p.Q790H | Missense Mutation (SNP) | VAF 37/304 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- QSOX2 | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- RAB37 | c.566+5G>T | Splice Region (SNP) | VAF 100/246 reads (41%) | called by muse, mutect2, varscan2
- RB1CC1 | c.568A>T p.T190S | Missense Mutation (SNP) | VAF 19/291 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.14); called by muse, mutect2
- RBBP6 | c.4816C>A p.Q1606K | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM25 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- RBM6 | c.2541G>T p.M847I | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- REG1B | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- RGPD3 | c.2893C>A p.Q965K | Missense Mutation (SNP) | VAF 120/724 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- RRP12 | c.1418+1G>A p.X473_splice | Splice Site (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2
- RSL1D1 | c.1126C>A p.P376T | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.702); called by muse, mutect2
- RUNX3 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SAG | c.182-1G>T p.X61_splice | Splice Site (SNP) | VAF 16/52 reads (31%) | called by muse, varscan2
- SCN11A | c.2299G>T p.G767W | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN2A | c.3056G>T p.R1019I | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.431); called by muse, mutect2
- SDK2 | c.4298G>T p.R1433L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SERPINA7 | c.896+1G>T p.X299_splice | Splice Site (SNP) | VAF 102/377 reads (27%) | called by muse, mutect2, varscan2
- SETX | c.6777G>C p.R2259S | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SGCG | c.332T>A p.V111E | Missense Mutation (SNP) | VAF 39/337 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SH3GL2 | c.491G>C p.R164P | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SKI | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- SLC4A10 | c.1663T>C p.Y555H (on ENST00000446997 / NM_001354461.2; = p.Y525H on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLCO1B1 | c.395C>G p.S132* | Nonsense Mutation (SNP) | VAF 85/250 reads (34%) | called by muse, mutect2, varscan2
- SNX27 | c.985+8C>A | Splice Region (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- SORCS1 | c.2062del p.E688Kfs*94 | Frame Shift Del (DEL) | VAF 27/122 reads (22%) | called by mutect2, pindel, varscan2
- SORCS1 | c.2061G>T p.G687= | Splice Region (SNP) | VAF 30/114 reads (26%) | called by mutect2, varscan2
- SORCS3 | c.2187G>T p.Q729H | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.321); called by muse, varscan2
- SP140 | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 35/145 reads (24%) | called by muse, mutect2, varscan2
- SPECC1 | c.2225C>G p.A742G | Missense Mutation (SNP) | VAF 77/300 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SPEN | c.2687T>C p.V896A | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPESP1 | c.53C>G p.P18R | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.431); called by muse, mutect2
- SPTA1 | c.3164A>T p.Q1055L | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); called by mutect2, varscan2
- STON2 | c.1993C>T p.L665F (on ENST00000649389 / NM_001366849.2; = p.L608F on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- STYXL2 | c.1367A>T p.E456V | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- SUPV3L1 | c.2012A>G p.H671R | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYT6 | c.829C>A p.R277S (on ENST00000610222 / NM_001366225.1; = p.R192S on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TAAR8 | c.915G>T p.M305I | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TACR3 | c.1076T>C p.L359P | Missense Mutation (SNP) | VAF 52/359 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TADA2A | c.605-1G>T p.X202_splice | Splice Site (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- TBCD | c.2285C>T p.A762V | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TCAF2 | c.2275C>A p.L759M | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TENM2 | c.641C>G p.P214R | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TEX13C | c.2846A>T p.K949M | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TEX55 | c.1524C>A p.H508Q | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- TLN2 | c.7608G>T p.E2536D | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- TLR4 | c.2143G>T p.G715C (on ENST00000355622 / NM_138554.5; = p.G675C on NM_003266.4) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMLHE | c.416A>T p.E139V | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- TNS1 | c.1334G>T p.S445I | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2
- TOPAZ1 | c.2975T>A p.V992E | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- TRABD2B | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- TRAF5 | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRIM64C | c.646C>G p.Q216E | Missense Mutation (SNP) | VAF 71/492 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.006); called by muse, varscan2
- TRPM2 | c.2299C>A p.L767I | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TRPM6 | c.4523A>T p.Q1508L | Missense Mutation (SNP) | VAF 63/323 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TRPM6 | c.4009G>C p.A1337P | Missense Mutation (SNP) | VAF 60/334 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- TTN | c.41818G>T p.V13940F (on ENST00000591111; = p.V6516F on NM_003319.4) | Missense Mutation (SNP) | VAF 18/270 reads (7%) | PolyPhen possibly damaging (0.502); called by muse, mutect2
- TUBB6 | c.446C>A p.T149K | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- UMOD | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UNC13A | c.2726C>G p.A909G | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- UTP14A | c.1680C>A p.D560E | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.072); called by muse, varscan2
- VGLL3 | c.828G>T p.Q276H | Missense Mutation (SNP) | VAF 47/302 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS13C | c.10367C>T p.A3456V (on ENST00000644861 / NM_020821.3; = p.A3413V on NM_017684.5) | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0.443); called by muse, mutect2
- VWF | c.6253T>A p.C2085S | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR17 | c.176T>G p.L59R | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR24 | c.263A>T p.D88V (on ENST00000248142; = p.D26V on NM_032259.4) | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- WSCD2 | c.88G>T p.G30W | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XKR6 | c.1058G>T p.S353I | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZAN | c.4500C>A p.C1500* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- ZBTB8B | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZEB1 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 85/356 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFHX4 | c.7537C>T p.H2513Y | Missense Mutation (SNP) | VAF 26/430 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); called by muse, mutect2
- ZNF133 | c.1832G>T p.C611F (on ENST00000316358 / NM_001352454.2; = p.C610F on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- ZNF14 | c.1691G>T p.C564F | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF280A | c.953A>T p.H318L | Missense Mutation (SNP) | VAF 51/247 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- ZNF280B | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF366 | c.1897C>A p.P633T | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZNF521 | c.3344G>T p.R1115I | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF555 | c.1165A>T p.T389S | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF668 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 33/196 reads (17%) | called by muse, mutect2, varscan2
- ZNF729 | c.2152G>A p.G718S | Missense Mutation (SNP) | VAF 40/344 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- ZNF860 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 71/302 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- ZNRF4 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ZRSR2 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2
- ABCB11 | c.2217C>A p.A739= | Silent (SNP) | VAF 23/118 reads (19%) | called by muse, mutect2, varscan2
- ACTN3 | c.1821C>A p.I607= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- ANO3 | c.2481T>C p.N827= | Silent (SNP) | VAF 15/147 reads (10%) | called by muse, mutect2
- ANXA8 | c.216T>A p.T72= | Silent (SNP) | VAF 54/274 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.250C>A p.R84= | Silent (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- ASXL3 | c.2154G>T p.P718= | Silent (SNP) | VAF 43/236 reads (18%) | catalogued as rs370185733, COSV52471685; called by muse, mutect2, varscan2
- ATP2B2 | c.1617C>A p.T539= (on ENST00000352432; = p.T505= on NM_001683.5) | Silent (SNP) | VAF 50/314 reads (16%) | catalogued as COSV59498991; called by muse, mutect2, varscan2
- ATP2B2 | c.495C>A p.V165= | Silent (SNP) | VAF 78/292 reads (27%) | called by muse, mutect2, varscan2
- ATP4A | c.633C>A p.P211= | Silent (SNP) | VAF 20/135 reads (15%) | called by muse, mutect2, varscan2
- BAIAP3 | c.2091G>A p.L697= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs1179459089; called by muse, mutect2, varscan2
- C1QTNF8 | c.309G>A p.G103= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- C2orf16 | c.591G>T p.R197= | Silent (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2, varscan2
- CBLN2 | c.198G>A p.V66= | Silent (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- CNNM3 | c.855G>T p.R285= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1381405980; called by muse, mutect2, varscan2
- COL4A6 | c.43C>T p.L15= | Silent (SNP) | VAF 68/269 reads (25%) | called by muse, mutect2, varscan2
- COL5A1 | c.930G>T p.L310= | Silent (SNP) | VAF 38/240 reads (16%) | called by muse, mutect2, varscan2
- CSMD3 | c.5460G>T p.G1820= (on ENST00000297405 / NM_001363185.1; = p.G1716= on NM_052900.3) | Silent (SNP) | VAF 333/713 reads (47%) | catalogued as COSV52168987; called by muse, varscan2
- DGKD | c.993G>A p.G331= (on ENST00000264057 / NM_152879.3; = p.G287= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as rs1559548597; called by muse, mutect2, varscan2
- DNAH3 | c.9423C>A p.I3141= | Silent (SNP) | VAF 42/216 reads (19%) | called by muse, mutect2, varscan2
- DSPP | c.126G>A p.V42= | Silent (SNP) | VAF 22/372 reads (6%) | called by muse, mutect2
- ELOA2 | c.1347C>T p.A449= | Silent (SNP) | VAF 19/397 reads (5%) | called by muse, mutect2
- EPPK1 | c.4131G>T p.A1377= | Silent (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- FBXL7 | c.669C>T p.Y223= | Silent (SNP) | VAF 57/153 reads (37%) | catalogued as rs1474634874; called by muse, mutect2, varscan2
- FGF5 | c.573C>A p.A191= | Silent (SNP) | VAF 46/181 reads (25%) | catalogued as COSV100428114; called by muse, mutect2, varscan2
- GLIS1 | c.1293G>T p.L431= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV56556256; called by muse, mutect2, varscan2
- GPAT2 | c.1617G>A p.L539= | Silent (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- GTF3C2 | c.2091G>A p.K697= | Silent (SNP) | VAF 30/242 reads (12%) | called by muse, mutect2, varscan2
- HAP1 | c.1161G>A p.L387= | Silent (SNP) | VAF 14/201 reads (7%) | catalogued as rs1170473985; called by muse, mutect2
- HDAC6 | c.345C>A p.I115= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- HEATR1 | c.2124G>T p.L708= | Silent (SNP) | VAF 32/258 reads (12%) | called by muse, varscan2
- IL18R1 | c.30T>G p.L10= | Silent (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- LRRC7 | c.2472C>A p.A824= (on ENST00000651989 / NM_001370785.2; = p.A791= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- MUC5B | c.6933C>T p.T2311= | Silent (SNP) | VAF 31/270 reads (11%) | called by muse, mutect2, varscan2
- MYO16 | c.3198G>A p.G1066= | Silent (SNP) | VAF 30/269 reads (11%) | catalogued as rs1326074883; called by muse, mutect2, varscan2
- MYO16 | c.3960C>T p.S1320= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs147869634, COSV100696716; called by muse, mutect2, varscan2
- MYT1L | c.2928C>T p.C976= | Silent (SNP) | VAF 19/131 reads (15%) | called by muse, mutect2, varscan2
- NFE2L3 | c.291G>T p.A97= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs993501236; called by muse, mutect2, varscan2
- NPAP1 | c.1986C>A p.P662= | Silent (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2, varscan2
- NRDC | c.1416A>G p.P472= | Silent (SNP) | VAF 32/195 reads (16%) | catalogued as rs1248905388; called by muse, mutect2, varscan2
- NSUN5 | c.864G>T p.A288= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as rs368355769, COSV53094078, COSV99392381; called by muse, mutect2, varscan2
- NTNG1 | c.1602C>A p.A534= (on ENST00000370068 / NM_001113226.3; = p.A433= on NM_014917.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- OBP2A | c.240G>T p.L80= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV59791194; called by muse, mutect2, varscan2
- OR11L1 | c.234G>T p.V78= | Silent (SNP) | VAF 23/222 reads (10%) | called by muse, mutect2
- OR5B2 | c.237C>A p.V79= | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as COSV56909737; called by muse, mutect2
- OR5D14 | c.87C>A p.L29= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as rs1289880453; called by muse, mutect2, varscan2
- OR8H3 | c.618C>A p.T206= | Silent (SNP) | VAF 51/175 reads (29%) | called by muse, mutect2, varscan2
- OR8J1 | c.864C>A p.P288= | Silent (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- PAPPA2 | c.2166T>C p.Y722= | Silent (SNP) | VAF 16/62 reads (26%) | called by mutect2, varscan2
- PCDH15 | c.4695C>A p.G1565= | Silent (SNP) | VAF 82/289 reads (28%) | catalogued as COSV57321156; called by muse, mutect2, varscan2
- PCDH15 | c.1608A>T p.A536= | Silent (SNP) | VAF 44/358 reads (12%) | called by muse, mutect2, varscan2
- PCSK1 | c.2133C>A p.S711= | Silent (SNP) | VAF 85/296 reads (29%) | called by muse, mutect2, varscan2
- PDE4B | c.1251G>T p.S417= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV58470059; called by muse, mutect2, varscan2
- PIGO | c.1392C>T p.I464= | Silent (SNP) | VAF 42/269 reads (16%) | catalogued as rs149790500; ClinVar: likely benign; called by muse, mutect2, varscan2
- PKHD1L1 | c.5334C>T p.D1778= | Silent (SNP) | VAF 159/306 reads (52%) | called by muse, mutect2, varscan2
- PPP1R16B | c.1476G>T p.L492= | Silent (SNP) | VAF 31/120 reads (26%) | called by muse, mutect2, varscan2
- RDH8 | c.985C>A p.R329= (on ENST00000651512; = p.R309= on NM_015725.4) | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV99408686; called by muse, mutect2, varscan2
- RGN | c.666A>T p.G222= | Silent (SNP) | VAF 18/116 reads (16%) | called by muse, mutect2, varscan2
- RHOXF2 | c.462A>G p.Q154= | Silent (SNP) | VAF 39/332 reads (12%) | catalogued as rs782058881; called by muse, mutect2, varscan2
- RP1L1 | c.2307G>A p.R769= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- S100G | c.123C>A p.P41= | Silent (SNP) | VAF 17/114 reads (15%) | called by muse, mutect2, varscan2
- SAMD3 | c.1512T>A p.P504= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as COSV62385528; called by muse, mutect2, varscan2
- SCN10A | c.2940C>A p.P980= | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- SCNN1B | c.534A>T p.S178= | Silent (SNP) | VAF 35/220 reads (16%) | called by muse, mutect2, varscan2
- SERPINA6 | c.637C>T p.L213= | Silent (SNP) | VAF 44/265 reads (17%) | catalogued as COSV100448453; called by muse, mutect2, varscan2
- SI | c.564G>T p.T188= | Silent (SNP) | VAF 75/404 reads (19%) | called by muse, varscan2
- SI | c.414A>T p.L138= | Silent (SNP) | VAF 90/466 reads (19%) | called by muse, mutect2, varscan2
- SLC27A6 | c.405C>T p.L135= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- SLC9C2 | c.2406G>A p.L802= | Silent (SNP) | VAF 46/166 reads (28%) | called by muse, mutect2, varscan2
- SLIT2 | c.381G>A p.A127= | Silent (SNP) | VAF 18/316 reads (6%) | catalogued as rs1336735058, COSV56565505, COSV99879578; called by muse, mutect2
- SPATA31D1 | c.729T>A p.L243= | Silent (SNP) | VAF 16/350 reads (5%) | called by muse, mutect2
- TAF2 | c.3492G>A p.K1164= | Silent (SNP) | VAF 311/654 reads (48%) | called by muse, mutect2, varscan2
- TAFA3 | c.36C>A p.G12= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV62624848; called by muse, mutect2, varscan2
- TARS1 | c.786G>T p.R262= | Silent (SNP) | VAF 42/392 reads (11%) | called by muse, mutect2, varscan2
- TAS2R41 | c.126G>T p.L42= | Silent (SNP) | VAF 33/232 reads (14%) | called by muse, mutect2, varscan2
- TENM1 | c.1035G>T p.L345= | Silent (SNP) | VAF 46/143 reads (32%) | called by muse, mutect2, varscan2
- TMC8 | c.607C>T p.L203= | Silent (SNP) | VAF 18/329 reads (5%) | called by muse, mutect2
- TRBV3-1 | c.27G>T p.V9= | Silent (SNP) | VAF 12/78 reads (15%) | called by muse, varscan2
- TRIM11 | c.816G>T p.V272= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as rs371952104; called by muse, mutect2, varscan2
- TRIM29 | c.66G>T p.P22= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs773439980, COSV100531420; called by muse, mutect2, varscan2
- TRIM33 | c.2751A>T p.T917= | Silent (SNP) | VAF 28/90 reads (31%) | called by muse, varscan2
- TRIM58 | c.1137T>C p.N379= | Silent (SNP) | VAF 42/149 reads (28%) | called by muse, mutect2, varscan2
- TROAP | c.252G>T p.G84= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as rs764943094; called by muse, mutect2, varscan2
- TRPC4 | c.225C>A p.L75= | Silent (SNP) | VAF 38/159 reads (24%) | called by muse, varscan2
- TTN | c.94593C>A p.T31531= (on ENST00000591111; = p.T24107= on NM_003319.4) | Silent (SNP) | VAF 35/259 reads (14%) | called by muse, mutect2, varscan2
- UBQLNL | c.216G>T p.L72= | Silent (SNP) | VAF 31/138 reads (22%) | called by muse, mutect2, varscan2
- WDFY3 | c.8709G>T p.V2903= | Silent (SNP) | VAF 46/166 reads (28%) | catalogued as COSV55700713; called by muse, mutect2, varscan2
- ZNF280A | c.204A>T p.P68= | Silent (SNP) | VAF 18/104 reads (17%) | called by muse, mutect2, varscan2
- ZNF423 | c.2085C>A p.T695= (on ENST00000563137 / NM_001379286.1; = p.T687= on NM_015069.4) | Silent (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2, varscan2
- ZNF469 | c.3270C>G p.G1090= (on ENST00000437464; = p.G1118= on NM_001367624.2) | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- ZNF469 | c.4416T>A p.S1472= (on ENST00000437464; = p.S1500= on NM_001367624.2) | Silent (SNP) | VAF 80/386 reads (21%) | called by muse, mutect2, varscan2
- ZNF521 | c.3759A>T p.G1253= | Silent (SNP) | VAF 18/187 reads (10%) | called by muse, mutect2, varscan2
- AC007557.3 | n.2400G>T | RNA (SNP) | VAF 36/137 reads (26%) | called by muse, mutect2, varscan2
- AC011410.1 | n.120C>T | RNA (SNP) | VAF 13/178 reads (7%) | called by muse, mutect2
- AC090142.3 | chr8:104991665 G>A | 5'Flank (SNP) | VAF 22/410 reads (5%) | called by muse, mutect2
- ANKRD19P | n.30C>A | RNA (SNP) | VAF 26/322 reads (8%) | called by muse, mutect2
- ARHGAP22 | c.989-345G>T | Intron (SNP) | VAF 46/201 reads (23%) | called by muse, mutect2, varscan2
- ASCC1 | chr10:72096235 G>A | 3'Flank (SNP) | VAF 33/151 reads (22%) | called by muse, mutect2, varscan2
- AWAT2 | c.648-45G>T | Intron (SNP) | VAF 16/187 reads (9%) | called by muse, mutect2
- B3GALT5 | c.-523-7281G>T | Intron (SNP) | VAF 29/195 reads (15%) | called by muse, mutect2, varscan2
- C20orf197 | n.509G>C | RNA (SNP) | VAF 87/361 reads (24%) | called by muse, mutect2, varscan2
- CALCB | c.-7G>T | 5'UTR (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- CD247 | c.-41C>T | 5'UTR (SNP) | VAF 24/250 reads (10%) | called by muse, mutect2
- CD34 | c.973-150T>A | Intron (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2, varscan2
- CEP162 | c.172+1866G>T | Intron (SNP) | VAF 24/124 reads (19%) | catalogued as rs548948924; called by muse, mutect2, varscan2
- COL5A1 | c.654+7316C>T | Intron (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- CORO1B | c.756+321C>A | Intron (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- DOT1L | c.4606+1043G>C | Intron (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- ESRRB | c.1296+447T>C | Intron (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- GAPVD1 | c.2429-1828A>G | Intron (SNP) | VAF 20/185 reads (11%) | called by muse, mutect2, varscan2
- IDO2 | c.-18C>T | 5'UTR (SNP) | VAF 140/361 reads (39%) | called by muse, varscan2
- IL1RL1 | c.610+416T>C | Intron (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- IRF2 | c.87+247G>T | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- KCNK9 | c.*35G>T | Intron (SNP) | VAF 280/556 reads (50%) | called by muse, mutect2, varscan2
- KCNMA1 | c.3016+797A>T | Intron (SNP) | VAF 49/158 reads (31%) | called by muse, mutect2, varscan2
- MIR296 | chr20:58817702 C>A | 5'Flank (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- MMGT1 | c.-58G>C | 5'UTR (SNP) | VAF 16/231 reads (7%) | called by muse, mutect2
- MMP26 | c.-145+92622C>A | Intron (SNP) | VAF 12/134 reads (9%) | catalogued as rs561325859; called by muse, mutect2
- MMP26 | c.-145+92623C>A | Intron (SNP) | VAF 12/134 reads (9%) | catalogued as rs777836233, COSV59033865; called by muse, mutect2
- MPDZ | c.*8G>T | 3'UTR (SNP) | VAF 7/58 reads (12%) | called by mutect2, varscan2
- MTBP | c.-21dup | 5'UTR (INS) | VAF 85/205 reads (41%) | called by mutect2, pindel, varscan2
- MTND6P20 | chr8:46843398 G>T | 3'Flank (SNP) | VAF 117/254 reads (46%) | called by muse, varscan2
- NDST3 | c.981+28A>T | Intron (SNP) | VAF 75/272 reads (28%) | called by muse, mutect2, varscan2
- NRXN1 | c.772+1063C>T | Intron (SNP) | VAF 22/354 reads (6%) | catalogued as rs184695687; ClinVar: uncertain significance; called by muse, mutect2
- NT5E | c.1360+433G>T | Intron (SNP) | VAF 39/150 reads (26%) | called by muse, mutect2, varscan2
- NXF5 | n.748C>A | RNA (SNP) | VAF 12/90 reads (13%) | called by mutect2, varscan2
- OPRM1 | c.-245G>T | 5'UTR (SNP) | VAF 18/69 reads (26%) | catalogued as COSV57680903; called by muse, mutect2, varscan2
- PCF11 | c.2092+22G>T | Intron (SNP) | VAF 62/219 reads (28%) | called by muse, mutect2, varscan2
- PNCK | c.69-75G>T | Intron (SNP) | VAF 9/17 reads (53%) | catalogued as rs1327520379; called by muse, mutect2, varscan2
- PNLIPRP1 | c.330+38C>A | Intron (SNP) | VAF 40/186 reads (22%) | called by muse, mutect2, varscan2
- PNLIPRP3 | c.-22G>A | 5'UTR (SNP) | VAF 34/227 reads (15%) | catalogued as rs368300426; called by muse, mutect2, varscan2
- RYR2 | c.14656-25G>A | Intron (SNP) | VAF 35/125 reads (28%) | catalogued as rs376695688; called by muse, mutect2, varscan2
- SLC25A13 | c.*722A>G | 3'UTR (SNP) | VAF 123/586 reads (21%) | called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088527 G>C | 3'Flank (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2
- SSPOP | n.3738G>T | RNA (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2, varscan2
- TMCO1 | c.*2254G>A | 3'UTR (SNP) | VAF 67/249 reads (27%) | called by muse, mutect2, varscan2
- TMEM70 | c.*818G>C | 3'UTR (SNP) | VAF 130/258 reads (50%) | called by muse, mutect2, varscan2
- TTBK2 | c.823-6535T>C | Intron (SNP) | VAF 14/159 reads (9%) | called by muse, mutect2
- XKR4 | c.806+58308G>T | Intron (SNP) | VAF 23/333 reads (7%) | called by muse, mutect2
- ZNF165 | chr6:28091297 G>A | 3'Flank (SNP) | VAF 12/276 reads (4%) | called by muse, mutect2
- ZNF30 | c.-37C>T | 5'UTR (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2, varscan2
